Somatic mutation profile of tumor specimen TCGA-32-4213-01A (aliquot TCGA-32-4213-01A-01D-1353-08) from TCGA case TCGA-32-4213, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.2 years (17,237 days).
Specimen TCGA-32-4213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bd0a1e8-69c9-4f98-aca8-99babc93d442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-4213-10A (Blood Derived Normal), aliquot TCGA-32-4213-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95811b8d-1aff-4820-a9a2-5c04fa566754

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 4, Intron 2, RNA 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.2141C>A p.P714Q | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.167); catalogued as COSV53577657, COSV53577671; called by muse, mutect2, varscan2
- AHNAK2 | c.6616C>A p.L2206I | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV60920430; called by muse, mutect2, varscan2
- ARHGEF17 | c.5833A>T p.T1945S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV55234295; called by muse, mutect2, varscan2
- CDC42BPB | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63475697; called by muse, mutect2, varscan2
- CHD9 | c.8642C>A p.S2881Y (on ENST00000398510 / NM_001382353.1; = p.S2865Y on NM_025134.7) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54612125, COSV54612424; called by muse, mutect2, varscan2
- DNAH5 | c.3115G>T p.E1039* | Nonsense Mutation (SNP) | VAF 102/250 reads (41%) | catalogued as COSV54236073; called by muse, mutect2, varscan2
- EGF | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480805, COSV99491272; called by muse, mutect2, varscan2
- FAM9A | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 161/560 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV66813467; called by muse, mutect2, varscan2
- FOXP2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV63488801; called by muse, mutect2, varscan2
- GABRG2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62715377, COSV62715450; called by muse, varscan2
- GALNT17 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61170392; called by muse, varscan2
- HEY2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV64240196; called by mutect2, varscan2
- HLA-DRA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as rs754838655, COSV66622479; called by muse, mutect2, varscan2
- KDM4D | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs372591204; called by muse, mutect2
- MAN2A2 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs114870914, COSV64638825; called by muse, mutect2, varscan2
- MAP3K7CL | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.369); catalogued as rs766097899, COSV54510580; called by muse, mutect2, varscan2
- MUC3A | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT deleterious, low confidence (0); catalogued as rs1384125848, COSV100113814; called by muse, mutect2, varscan2
- NPTX1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 115/362 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1447587351, COSV60774615; called by muse, mutect2, varscan2
- NRK | c.3683C>A p.S1228Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs753590476, COSV54600308; called by muse, mutect2, varscan2
- PFKFB1 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 30/91 reads (33%) | PolyPhen benign (0); catalogued as COSV66628772; called by muse, mutect2, varscan2
- POC1B | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV57966504; called by muse, mutect2, varscan2
- SLC7A13 | c.1179+1G>A p.X393_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as rs139960114; called by muse, mutect2, varscan2
- SON | c.3707A>G p.D1236G | Missense Mutation (SNP) | VAF 133/439 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV51663203; called by muse, mutect2, varscan2
- SP100 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60846846; called by muse, mutect2, varscan2
- SPAG16 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55987383; called by muse, mutect2, varscan2
- TAS2R5 | c.137del p.L46Pfs*16 | Frame Shift Del (DEL) | VAF 52/161 reads (32%) | catalogued as COSV56095070; called by mutect2, pindel, varscan2
- TPTE | c.832C>A p.H278N (on ENST00000618007 / NM_199261.4; = p.H260N on NM_199259.4) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs778442291; called by muse, mutect2, varscan2
- TTN | c.88259G>A p.R29420H (on ENST00000591111; = p.R21996H on NM_003319.4) | Missense Mutation (SNP) | VAF 150/487 reads (31%) | PolyPhen probably damaging (0.917); catalogued as rs727504923, COSV60164458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV67139566; called by muse, mutect2, varscan2
- TYSND1 | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54643391; called by muse, mutect2, varscan2
- USP42 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs747842497, COSV60358377; called by muse, mutect2, varscan2
- ARHGEF40 | c.3760_3762del p.L1254del | In Frame Del (DEL) | VAF 7/29 reads (24%) | called by pindel, varscan2
- DNAH8 | c.2438del p.D813Afs*7 | Frame Shift Del (DEL) | VAF 45/182 reads (25%) | called by mutect2, pindel, varscan2
- PTEN | c.959dup p.L320Ffs*5 | Frame Shift Ins (INS) | VAF 57/141 reads (40%) | called by mutect2, pindel, varscan2
- RB1 | c.1450_1451del p.M484Vfs*8 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2
- TIA1 | c.159del p.H54Mfs*10 | Frame Shift Del (DEL) | VAF 64/226 reads (28%) | called by mutect2, pindel, varscan2
- AAAS | c.342C>T p.A114= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV52933420; called by muse, mutect2, varscan2
- CD6 | c.1674G>C p.P558= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as COSV57840195; called by muse, mutect2, varscan2
- EPHX2 | c.459G>A p.S153= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs146337543; called by muse, mutect2, varscan2
- GPRIN2 | c.1068G>A p.A356= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs782016007, COSV65401508, COSV65402905; called by muse, mutect2, varscan2
- HNRNPR | c.477G>A p.V159= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as COSV56422669; called by muse, mutect2, varscan2
- MRC1 | c.2556C>T p.N852= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- RASSF6 | c.189C>A p.T63= (on ENST00000342081 / NM_201431.2; = p.T31= on NM_177532.5) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs755189760, COSV56719406; called by muse, mutect2
- TXNIP | c.453C>T p.V151= | Silent (SNP) | VAF 67/290 reads (23%) | catalogued as rs782806656, COSV65220748; called by muse, mutect2, varscan2
- TYMP | c.351C>T p.S117= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV52688450; called by muse, mutect2, varscan2
- ZC3H12B | c.1671C>T p.I557= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as rs1193154232, COSV59046037, COSV59049535; called by muse, mutect2
- IGFN1 | c.1242-26C>T | Intron (SNP) | VAF 39/130 reads (30%) | catalogued as rs747766879, COSV55176677; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18420C>A | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as COSV67446133; called by muse, mutect2, varscan2
- SNORD115-33 | n.19G>A | RNA (SNP) | VAF 159/464 reads (34%) | catalogued as rs566553546; called by muse, mutect2, varscan2
- TMEM183B | n.8G>A | RNA (SNP) | VAF 9/18 reads (50%) | catalogued as rs763626034, COSV60378129; called by muse, varscan2
